Somatic mutation profile of tumor specimen TCGA-EO-A3AZ-01A (aliquot TCGA-EO-A3AZ-01A-12D-A19Y-09) from TCGA case TCGA-EO-A3AZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 80.0 years (29,234 days).
Specimen TCGA-EO-A3AZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84c43e1b-8df9-4da5-8296-5e21df8afe47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A3AZ-10A (Blood Derived Normal), aliquot TCGA-EO-A3AZ-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17252693-b245-417c-9b8e-d147031d1b14

The open-access MAF lists 1,157 somatic variants for this specimen: 879 protein-altering or splice-affecting, 245 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 611, Silent 245, Frame Shift Del 156, Nonsense Mutation 48, Frame Shift Ins 30, Splice Site 15, Intron 14, Splice Region 11, 3'UTR 6, In Frame Del 5, RNA 5, 5'UTR 5.

Variants (750 of 1,157; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSL | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs756210458, CM990118, COSV99342243; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ALG6 | c.1194del p.F398Lfs*2 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs1207096732; ClinVar: likely pathogenic; called by mutect2, pindel
- ATM | c.8287C>T p.R2763* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as rs876659872, CM080077, COSV53734668; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.1961del p.K654Sfs*47 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | catalogued as rs80357522, CD076746, CD951610; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 26/188 reads (14%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- DYSF | c.937+1G>A p.X313_splice | Splice Site (SNP) | VAF 30/120 reads (25%) | catalogued as rs201869739, CS024009, COSV50563997, COSV50598174; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJA3 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs864309687, CM071794, COSV53834152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLI3 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 17/118 reads (14%) | catalogued as rs121917714, CM990706, COSV67885757; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRXCR1 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 29/118 reads (25%) | catalogued as rs769983282, CM163818, COSV67670429; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MSH2 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as rs63750843, CM055994, COSV99253860; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1276+2T>C p.X426_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as rs267607953, CS068357, COSV99253861; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.741del p.K247Nfs*32 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs267608041; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.4330A>G p.K1444E (on ENST00000358273 / NM_001042492.3; = p.K1423E on NM_000267.3) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs137854550, CM143401, CM145726, CM920506, COSV62204136, COSV62222725; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: drug response / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553579488, COSV51846923; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.1101-2A>G p.X367_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as rs587781664, CS111031, COSV52676811, COSV52714663, COSV53348267; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- VWF | c.2279G>A p.R760H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs61748467, CM095392, COSV99779085; ClinVar: not provided / pathogenic; called by muse, varscan2
- AARS2 | c.2942C>T p.A981V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV99771445; called by muse, mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | catalogued as rs771808127, COSV55113098; called by mutect2, pindel, varscan2
- ABCC1 | c.3976G>A p.V1326M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364759840, COSV60691506; called by muse, mutect2, varscan2
- ABI2 | c.613C>T p.R205C (on ENST00000295851 / NM_001375719.1; = p.R199C on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs769362739, COSV53690602, COSV99651806; called by muse, mutect2, varscan2
- AC004922.1 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs529951024, COSV53556256; called by muse, mutect2, varscan2
- ACADVL | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM132669, COSV99138523; called by muse, mutect2
- ACIN1 | c.3273+2T>A p.X1091_splice | Splice Site (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99399638; called by muse, mutect2, varscan2
- ACLY | c.2125G>T p.G709* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV100709698; called by muse, varscan2
- ACTG2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs765884368, COSV61827627; called by muse, mutect2, varscan2
- ACVRL1 | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as CM159625, COSV101187916; called by muse, mutect2
- ADAM32 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs544708309, COSV101165350; called by muse, mutect2, varscan2
- ADAMTS13 | c.3103C>T p.R1035C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782414383, COSV100747084; called by muse, mutect2
- ADAMTS9 | c.4549G>A p.V1517I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.021); catalogued as rs868532784, COSV55792269; called by muse, mutect2, varscan2
- ADGRB3 | c.3042G>A p.W1014* | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as COSV53250784, COSV99485063; called by muse, mutect2, varscan2
- ADGRF5 | c.1421C>A p.T474K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); catalogued as COSV99345613; called by muse, mutect2
- ADGRG4 | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374701309, COSV54962769; called by muse, mutect2, varscan2
- ADGRG6 | c.3121A>G p.I1041V | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.217); catalogued as COSV99747196; called by muse, mutect2, varscan2
- ADPRHL1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as rs761364646, COSV100215196; called by muse, mutect2, varscan2
- AEBP2 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs1446877653, COSV56863849, COSV99857835; called by muse, mutect2, varscan2
- AGO3 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.483); catalogued as rs761567226, COSV99868612; called by muse, mutect2, varscan2
- AHNAK2 | c.1976del p.K659Rfs*5 | Frame Shift Del (DEL) | VAF 19/158 reads (12%) | catalogued as rs1178630013; called by mutect2, pindel, varscan2
- AIDA | c.237C>T p.S79= | Splice Region (SNP) | VAF 14/79 reads (18%) | catalogued as rs756473755, COSV100388285; called by muse, mutect2, varscan2
- AKAP13 | c.5699C>T p.S1900L (on ENST00000394518 / NM_007200.5; = p.S1904L on NM_006738.6) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs371321602; called by muse, mutect2, varscan2
- AKAP6 | c.6592T>C p.F2198L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs1383915753, COSV99800864; called by muse, mutect2
- AKR1C2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101060465; called by muse, mutect2, varscan2
- AKTIP | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.985); catalogued as rs779924211, COSV55815268; called by muse, mutect2
- AL669918.1 | c.2401G>A p.G801R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1467359426, COSV101441046; called by muse, mutect2, varscan2
- ALAS2 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as HM040078, COSV100238338; called by mutect2, varscan2
- ALMS1 | c.11876T>C p.V3959A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV100042488; called by muse, mutect2, varscan2
- AMPD3 | c.1531C>T p.R511* (on ENST00000396553 / NM_001025389.2; = p.R520* on NM_000480.3) | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as rs150860475; called by muse, mutect2, varscan2
- ANAPC4 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | catalogued as COSV100194005; called by muse, mutect2, varscan2
- ANKRD28 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs138255179, COSV101080659; called by muse, mutect2, varscan2
- ANKRD35 | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs782139836, COSV100841734, COSV100841762; called by muse, mutect2, varscan2
- ANKRD55 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs774118271, COSV100591015; called by muse, mutect2, varscan2
- ANKS6 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs770988126, COSV62050350; called by muse, mutect2
- ANO4 | c.1619C>T p.A540V (on ENST00000392977 / NM_001286615.2; = p.A505V on NM_178826.4) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.617); catalogued as rs1014816581, COSV100152887; called by muse, mutect2, varscan2
- ANO6 | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.887); catalogued as rs761048570, COSV57658152; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs759218332; called by mutect2, varscan2
- AP1S2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.238); catalogued as COSV57063747; called by muse, mutect2, varscan2
- APP | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200396597, COSV100695759, COSV60999108; called by muse, mutect2, varscan2
- APP | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs200103591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARF1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as rs1382592951, COSV55254161; called by muse, mutect2
- ARHGAP32 | c.5989G>A p.V1997M (on ENST00000310343 / NM_001378025.1; = p.V1648M on NM_014715.4) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs141193303; called by muse, mutect2, varscan2
- ARHGAP35 | c.494A>T p.D165V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101351054; called by muse, varscan2
- ARHGAP35 | c.4253C>T p.T1418M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.422); catalogued as COSV101351060; called by mutect2, varscan2
- ARHGEF28 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756328784, COSV55265469; called by muse, mutect2, varscan2
- ARID1A | c.1859C>A p.S620Y | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100251716; called by muse, mutect2, varscan2
- ARID1A | c.6466A>G p.S2156G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1191962249, COSV100251718; called by muse, mutect2, varscan2
- ARSG | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs769238862, COSV100048418; called by muse, mutect2, varscan2
- ASB14 | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99897703; called by muse, mutect2, varscan2
- ASCC2 | c.1160+1G>A p.X387_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100316268; called by muse, mutect2, varscan2
- ASH2L | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs140501294; called by mutect2, varscan2
- ASXL2 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV55465862; called by muse, mutect2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs771531141; called by mutect2, varscan2
- ATRX | c.5817del p.D1940Ifs*15 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | catalogued as COSV100969996; called by pindel, varscan2
- ATRX | c.5698-1G>T p.X1900_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | catalogued as rs1557086190, COSV100970786, COSV64881768; called by muse, mutect2, varscan2
- AVIL | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148973636; called by muse, mutect2, varscan2
- AXL | c.2111G>A p.R704H (on ENST00000301178 / NM_021913.5; = p.R695H on NM_001699.6) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748730668, COSV56576031; called by muse, mutect2, varscan2
- B3GNT4 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs942692043, COSV57336917; called by muse, mutect2, varscan2
- BABAM1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs1230353465, COSV100845734; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1307del p.P436Hfs*60 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1405664842, COSV50055281; called by mutect2, pindel, varscan2
- BCAM | c.1884C>T p.C628= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99538713; called by muse, mutect2
- BCAS3 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101175682, COSV101175922; called by muse, mutect2, varscan2
- BCAS3 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs757599517, COSV101175923; called by muse, mutect2, varscan2
- BCL2L11 | c.457C>T p.R153W (on ENST00000393256 / NM_138621.5; = p.R93W on NM_006538.5) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146318804, COSV100427572; called by muse, mutect2
- BCR | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs182865213, COSV59930456; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs759565497, COSV99958764; called by muse, mutect2, varscan2
- BMP2K | c.2542G>A p.V848M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV99785101; called by muse, mutect2, varscan2
- BPIFB1 | c.1105A>G p.S369G | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV99487382; called by muse, mutect2, varscan2
- BRCA1 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.759); catalogued as COSV58788433; called by muse, mutect2, varscan2
- BRSK1 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.692); catalogued as COSV100473547; called by muse, mutect2, varscan2
- BTAF1 | c.5122G>A p.V1708I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756135288, COSV99795353; called by muse, mutect2, varscan2
- BTBD7 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs61747488, COSV100108036, COSV54138552; called by muse, mutect2, varscan2
- BUB3 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs770965383, COSV100922190; called by muse, mutect2, varscan2
- C11orf24 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs769363268, COSV58506442; called by muse, varscan2
- C12orf29 | c.275del p.N92Ifs*36 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs1225174111; called by mutect2, pindel, varscan2
- C1orf189 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV100880976; called by muse, mutect2, varscan2
- C3AR1 | c.1148_1150dup p.V383dup | In Frame Ins (INS) | VAF 12/54 reads (22%) | catalogued as rs988981035; called by mutect2, varscan2
- C5 | c.4144G>A p.D1382N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as rs772720068, COSV99797883; called by muse, mutect2, varscan2
- C6orf226 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1398291363, COSV100491700; called by muse, mutect2
- CACNA1G | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1393519989, COSV61728734; ClinVar: uncertain significance; called by muse, mutect2
- CACNA2D3 | c.1389G>T p.Q463H | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV99873599; called by muse, mutect2
- CACNA2D4 | c.3277C>T p.R1093* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1555173467, COSV99765686; called by muse, mutect2, varscan2
- CALD1 | c.2327G>A p.R776Q (on ENST00000361675 / NM_033138.4; = p.R521Q on NM_004342.7) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs571684749, COSV62647050; called by muse, mutect2, varscan2
- CAMSAP1 | c.3736G>A p.E1246K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.845); catalogued as rs781710864, COSV100409863; called by mutect2, varscan2
- CAPRIN1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1164896233, COSV100403891; called by muse, mutect2, varscan2
- CASP8 | c.1294C>T p.R432* (on ENST00000432109 / NM_033355.3; = p.R449* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as rs931648756, COSV51845077; called by muse, varscan2
- CATSPER1 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 36/143 reads (25%) | catalogued as rs374112491; called by muse, mutect2, varscan2
- CATSPERB | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs754871877, COSV99831280; called by muse, mutect2, varscan2
- CBFB | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1467426352, COSV51998270; called by muse, mutect2, varscan2
- CCDC136 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as rs759698253, COSV99922642; called by muse, mutect2, varscan2
- CCDC146 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751587535, COSV99592605; called by muse, mutect2, varscan2
- CCDC167 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs781100483, COSV64982814; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 19/106 reads (18%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC83 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs1178704715, COSV99721695; called by muse, mutect2, varscan2
- CCDC90B | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99475309; called by muse, mutect2, varscan2
- CCR3 | c.701del p.K234Sfs*52 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs761073142; called by mutect2, varscan2
- CCT2 | c.1586T>C p.V529A | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV100167617; called by muse, mutect2, varscan2
- CDC123 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.431); catalogued as rs199948914, COSV55396594; called by muse, mutect2, varscan2
- CDC20B | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99696913; called by muse, mutect2, varscan2
- CDC42BPA | c.5126del p.P1709Qfs*56 (on ENST00000334218 / NM_001366019.2; = p.P1696Qfs*56 on NM_003607.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | catalogued as rs869029351; called by mutect2, pindel, varscan2
- CDC42BPA | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100505108; called by muse, mutect2, varscan2
- CDC73 | c.530T>C p.M177T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV100813871; called by muse, mutect2, varscan2
- CDH1 | c.2261A>G p.Y754C | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs767613429, COSV99931924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH16 | c.712T>C p.W238R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100233882; called by muse, mutect2, varscan2
- CDK2AP1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV55542980; called by muse, mutect2
- CEACAM1 | c.557del p.P186Rfs*36 | Frame Shift Del (DEL) | VAF 29/154 reads (19%) | catalogued as COSV50726523; called by mutect2, varscan2
- CENPE | c.4994C>T p.T1665M | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781248304, COSV54384026; called by muse, mutect2, varscan2
- CFAP65 | c.2434del p.L812Wfs*56 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as COSV100444835; called by mutect2, pindel, varscan2
- CHD4 | c.3371C>T p.T1124I (on ENST00000357008 / NM_001363606.2; = p.T1137I on NM_001273.5) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV100538046; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 31/123 reads (25%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHD7 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1384228127, COSV71112437; called by muse, mutect2, varscan2
- CHD7 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs587783435, CM149843, COSV71107289; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST12 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756344721, COSV51674702; called by muse, mutect2, varscan2
- CKMT1B | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143381903; called by muse, mutect2, varscan2
- CLDN10 | c.126G>T p.W42C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100971092; called by muse, mutect2, varscan2
- CLIP4 | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs773401220, COSV60749724; called by muse, mutect2, varscan2
- CLMN | c.2845G>A p.A949T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100112418; called by muse, mutect2, varscan2
- CLMN | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54181966; called by muse, mutect2, varscan2
- CNGA2 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs141559818, COSV61703782; called by muse, mutect2, varscan2
- CNGB3 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761282523, COSV100182008; called by muse, mutect2, varscan2
- CNIH3 | c.81C>T p.H27= | Splice Region (SNP) | VAF 17/85 reads (20%) | catalogued as COSV99685828; called by muse, mutect2, varscan2
- CNN2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.141); catalogued as rs151328473; called by muse, varscan2
- CNOT10 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV59390664; called by muse, mutect2, varscan2
- CNTN5 | c.303del p.F101Lfs*19 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as COSV99678890; called by mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | catalogued as rs748995811; called by mutect2, varscan2
- COL14A1 | c.4861C>T p.R1621C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs551717415, COSV99919312; called by muse, mutect2, varscan2
- COL18A1 | c.3919G>A p.G1307R (on ENST00000359759 / NM_130444.3; = p.G1072R on NM_030582.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs576719084, COSV60588076; called by mutect2, varscan2
- COL5A2 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); catalogued as COSV100880340; called by muse, mutect2, varscan2
- COL9A1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs746534856, COSV100611161; called by muse, mutect2, varscan2
- CPS1 | c.3843G>T p.K1281N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV51816024, COSV99243041; called by muse, mutect2, varscan2
- CRADD | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100257613, COSV60552406; called by muse, mutect2, varscan2
- CRAMP1 | c.3751C>T p.R1251* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs1567464943, COSV50188999, COSV99245788; called by muse, mutect2, varscan2
- CREB3 | c.394_396del p.K132del | In Frame Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs1430689636; called by mutect2, pindel, varscan2
- CRTAC1 | c.422-1G>T p.X141_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100085533, COSV54006551; called by muse, mutect2, varscan2
- CRYBB3 | c.470+1G>A p.X157_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as rs754250272, COSV53194144; called by muse, mutect2, varscan2
- CSMD1 | c.6316G>A p.V2106M (on ENST00000520002; = p.V2105M on NM_033225.6) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764452740, COSV59303920; called by muse, mutect2, varscan2
- CSPP1 | c.2402C>T p.A801V (on ENST00000676605; = p.A760V on NM_024790.6) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs376549634, COSV99138569; called by muse, varscan2
- CSRNP3 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs183252532, COSV100085517, COSV58778076; called by muse, mutect2, varscan2
- CTAGE15 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769888736, COSV101372149; called by muse, mutect2, varscan2
- CTNNA3 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101046905, COSV101049310; called by muse, mutect2
- CTR9 | c.3145C>T p.R1049* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as rs1160779844, COSV100797363; called by muse, mutect2, varscan2
- CTSA | c.990dup p.C331Lfs*56 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | catalogued as rs758642867; called by mutect2, varscan2
- CTSG | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV99361527; called by muse, mutect2, varscan2
- CTSH | c.209A>T p.N70I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV99585501; called by muse, mutect2, varscan2
- CTTN | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200865893, COSV100096929, COSV100097710; called by muse, mutect2, varscan2
- CTTNBP2 | c.3947G>A p.R1316H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs138985857; called by muse, mutect2, varscan2
- CWC22 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs767672916, COSV99844290; called by muse, mutect2, varscan2
- CWF19L2 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99979028; called by muse, mutect2, varscan2
- CYP20A1 | c.903del p.K301Nfs*6 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs778884333; called by mutect2, varscan2
- CYP2C19 | c.785A>G p.D262G | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100990505; called by muse, mutect2, varscan2
- CYP4F3 | c.1181del p.P394Qfs*85 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs763457380, COSV55409152; called by mutect2, pindel
- CYP4V2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as rs749940173, COSV101114861; called by muse, mutect2, varscan2
- CYP51A1 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99133827; called by muse, mutect2, varscan2
- DAGLA | c.2882G>A p.R961H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as rs756782391, COSV57196844; called by muse, mutect2
- DAPK2 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs775505588, COSV99977407; called by muse, mutect2, varscan2
- DBN1 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1165123989, COSV52788825, COSV52792976; called by muse, mutect2, varscan2
- DCAF4L2 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); catalogued as rs1222870245, COSV60482942, COSV60484032; called by muse, mutect2, varscan2
- DCAF5 | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV58458616; called by muse, mutect2, varscan2
- DCAF5 | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV100432490; called by muse, mutect2, varscan2
- DCHS1 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs187784912, COSV55034085; called by muse, mutect2, varscan2
- DCTN3 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1020680836, COSV99426652; called by muse, mutect2, varscan2
- DDX47 | c.426del p.K142Nfs*4 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as COSV100774658; called by mutect2, pindel, varscan2
- DENND2A | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs967844138, COSV99326149; called by muse, mutect2, varscan2
- DENND3 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs749614133, COSV99370973; called by muse, mutect2, varscan2
- DENND5A | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300066037, COSV60231610; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as COSV59384233; called by mutect2, varscan2
- DIO2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs200301817, COSV70446612; called by muse, mutect2, varscan2
- DISP1 | c.800A>G p.D267G | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.125); catalogued as COSV99451031; called by muse, mutect2, varscan2
- DLG4 | c.1651C>A p.L551I (on ENST00000399506 / NM_001321075.3; = p.L594I on NM_001365.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100263713; called by muse, mutect2, varscan2
- DMBT1 | c.7066G>A p.D2356N (on ENST00000338354 / NM_001377530.1; = p.D1599N on NM_004406.3) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs369691816; called by muse, mutect2, varscan2
- DMTN | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1224680181, COSV56112985; called by muse, mutect2
- DMXL1 | c.5032C>T p.R1678C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774942375, COSV60710889; called by muse, mutect2, varscan2
- DNAAF3 | c.1330G>A p.G444R (on ENST00000524407 / NM_001256715.2; = p.G491R on NM_178837.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs562819833, COSV61275125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH10 | c.296G>A p.R99Q (on ENST00000409039; = p.R38Q on NM_207437.3) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); catalogued as rs149272124, COSV101292258; called by muse, mutect2, varscan2
- DNAH10 | c.7729C>T p.R2577C (on ENST00000409039; = p.R2516C on NM_207437.3) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs748816266, COSV68992301; called by muse, mutect2, varscan2
- DNAH17 | c.6887A>G p.D2296G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV101102338; called by muse, mutect2
- DNAH2 | c.4597del p.R1533Afs*37 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs1567677271, COSV66727252; called by mutect2, pindel, varscan2
- DNAH2 | c.12449G>A p.R4150Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as rs769020423, COSV66730533; called by muse, mutect2, varscan2
- DNAH8 | c.4418del p.N1473Ifs*15 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs778628413, COSV59486260; called by mutect2, varscan2
- DNAH8 | c.11026G>A p.A3676T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1030570618, COSV100542863; called by muse, mutect2, varscan2
- DNAJC3 | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV100953360; called by muse, mutect2, varscan2
- DNAJC6 | c.2450C>A p.P817H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54772386, COSV99674849; called by muse, mutect2, varscan2
- DNM2 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs587778235, COSV100117276; ClinVar: not provided / uncertain significance; called by muse, varscan2
- DNMT1 | c.2840C>T p.T947M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.322); catalogued as rs754990148, COSV100532482; ClinVar: uncertain significance; called by muse, varscan2
- DOCK11 | c.1740G>T p.Q580H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV52250490; called by muse, mutect2, varscan2
- DOCK3 | c.5354C>T p.T1785I | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1297871453, COSV99812010; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK5 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs751660728, COSV52825281; called by muse, varscan2
- DOLPP1 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as rs770551586, COSV59911119; called by muse, mutect2, varscan2
- DOP1A | c.3675T>G p.H1225Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.015); catalogued as COSV99381918; called by muse, mutect2, varscan2
- DRD2 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60762621; called by muse, mutect2, varscan2
- DSC1 | c.1790A>G p.D597G | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99937644; called by muse, mutect2, varscan2
- DSE | c.889A>G p.M297V | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1358374915, COSV100528555; called by muse, mutect2, varscan2
- DSP | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786204294, COSV65794210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777782794, COSV101131282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.12071G>A p.R4024Q (on ENST00000361203 / NM_001374722.1; = p.R1612Q on NM_015548.5) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1213650979, COSV99756008; called by muse, mutect2, varscan2
- DUSP10 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs769109743, COSV100100513; called by muse, mutect2, varscan2
- EHMT1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as CM165067, COSV100603852; called by muse, mutect2, varscan2
- ELAC2 | c.338T>C p.M113T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.848); catalogued as COSV100568499; called by muse, mutect2, varscan2
- ELAPOR1 | c.2452G>A p.V818I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs774651423, COSV64040033; called by muse, mutect2, varscan2
- ELAVL1 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.63); catalogued as rs1414902866, COSV100688367; called by muse, mutect2, varscan2
- EMC1 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs749905447, COSV64345176; called by muse, mutect2
- EMC1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748743672, COSV61886913; called by muse, mutect2, varscan2
- EPHA1 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759111320, COSV99313977; called by muse, varscan2
- EPHB1 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs777467287, COSV67665902, COSV67668344; called by muse, mutect2, varscan2
- EPHX2 | c.548dup p.L183Ffs*3 | Frame Shift Ins (INS) | VAF 32/116 reads (28%) | catalogued as rs1442463502; called by mutect2, varscan2
- ERICH1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.365); catalogued as rs369901140; called by muse, mutect2, varscan2
- EVL | c.244C>T p.R82* (on ENST00000402714 / NM_001330221.2; = p.R84* on NM_016337.3) | Nonsense Mutation (SNP) | VAF 16/81 reads (20%) | catalogued as rs1209498180, COSV67375671; called by muse, mutect2, varscan2
- EXOC3 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs1161125488, COSV100155338; called by mutect2, varscan2
- EYA1 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776314304, COSV100379413, COSV58158835; called by muse, mutect2, varscan2
- FAM229B | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100898150; called by muse, mutect2
- FAM71A | c.327del p.K109Nfs*8 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs749381759; called by mutect2, pindel, varscan2
- FAM71B | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs139475929; called by muse, mutect2, varscan2
- FAM83G | c.803G>A p.C268Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100525136; called by muse, mutect2, varscan2
- FANCM | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.046); catalogued as rs149473953, COSV57509221; called by muse, mutect2, varscan2
- FANCM | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs760204880, COSV99951062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANK1 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100904801; called by muse, mutect2
- FAR2 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs779272330, COSV99479096; called by muse, mutect2, varscan2
- FAS | c.403del p.C135Vfs*52 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs1564692984, CX113055, COSV58238368; called by mutect2, pindel, varscan2
- FASTKD1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs771797962, COSV71624107; called by muse, mutect2, varscan2
- FCSK | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99850880; called by mutect2, varscan2
- FEZF2 | c.1060A>G p.I354V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV99334724; called by muse, mutect2
- FGD1 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1421947550, COSV100911074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FHOD1 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1276907965, COSV99264122; called by muse, mutect2, varscan2
- FKRP | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100586637; called by muse, mutect2
- FMNL1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs781402859, COSV58955672; called by muse, mutect2
- FMNL3 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99526316; called by muse, mutect2, varscan2
- FMNL3 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.661); catalogued as rs1444059344, COSV53301283; called by muse, mutect2
- FOXP1 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1278430300, COSV100561699; called by muse, mutect2, varscan2
- FUT4 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV100708084; called by muse, mutect2, varscan2
- FYCO1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs774439678, COSV99945663, COSV99945762; called by muse, mutect2, varscan2
- FYN | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as rs761032788, COSV57621676; called by muse, mutect2, varscan2
- GALNTL5 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs200861829, COSV67179320; called by mutect2, varscan2
- GAPDHS | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs375182770; called by muse, mutect2, varscan2
- GBA | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs140955685, CM090423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCM1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs767355404, COSV99452361; called by muse, mutect2, varscan2
- GCSAM | c.151dup p.I51Nfs*5 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | catalogued as rs762814436; called by mutect2, varscan2
- GGNBP2 | c.1925T>G p.F642C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs372540972; called by muse, mutect2, varscan2
- GIGYF2 | c.2644C>T p.R882W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1036450266, COSV100771615; called by muse, mutect2, varscan2
- GIMAP8 | c.397T>C p.F133L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100217542, COSV56231171; called by muse, mutect2, varscan2
- GJA4 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60725645, COSV60726271; called by muse, varscan2
- GLIPR1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760892233, COSV56990489; called by muse, mutect2, varscan2
- GLRA1 | c.1265_1267del p.K422del (on ENST00000455880 / NM_001146040.2; = p.K414del on NM_000171.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 13/107 reads (12%) | catalogued as rs780743511; called by pindel, varscan2
- GMFG | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs142875775; called by muse, mutect2, varscan2
- GNA12 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV51739921; called by muse, mutect2, varscan2
- GNB4 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs186593898, COSV51709735; called by muse, mutect2, varscan2
- GNRH1 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as rs375970738, CM094312; called by muse, mutect2, varscan2
- GOLGA2 | c.2890C>T p.R964C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs775152615, COSV57851437; called by muse, mutect2, varscan2
- GOLGA3 | c.3304C>T p.R1102C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as rs866467183, COSV52634945; called by muse, mutect2, varscan2
- GOLT1B | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.388); catalogued as COSV99982006; called by muse, mutect2, varscan2
- GPATCH4 | c.629del p.K210Rfs*73 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as rs754640631; called by mutect2, varscan2
- GPLD1 | c.2221del p.L741* | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs749977099; called by pindel, varscan2
- GPN1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs566196119, COSV99270177; called by muse, mutect2, varscan2
- GPR119 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022160564, COSV52275468; called by muse, mutect2, varscan2
- GPR119 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.778); catalogued as rs201171290, COSV99358520, COSV99358629; called by muse, varscan2
- GPR139 | c.730del p.R244Afs*4 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as COSV58505701; called by mutect2, pindel, varscan2
- GPR21 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs999045682, COSV101016445; called by muse, mutect2, varscan2
- GPRC6A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369734914, COSV59953059; called by muse, mutect2, varscan2
- GPRIN3 | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.571); catalogued as COSV100310751; called by muse, mutect2, varscan2
- GRAMD1B | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs532856454, COSV100454750; called by muse, mutect2, varscan2
- GREM1 | c.277T>G p.W93G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277819, COSV100277948; called by muse, mutect2
- GRHL1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100257819; called by muse, mutect2, varscan2
- GRIN2A | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1489261681, COSV58032859, COSV58037182; ClinVar: not provided; called by muse, mutect2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GSTCD | c.1727A>G p.Q576R (on ENST00000360505 / NM_001031720.3; = p.Q489R on NM_024751.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs772646111, COSV64736701; called by muse, mutect2, varscan2
- HACL1 | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.196); catalogued as COSV100337249; called by muse, mutect2, varscan2
- HADHB | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs369313023, COSV58547490; called by muse, mutect2, varscan2
- HAT1 | c.597G>A p.W199* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99907970; called by muse, mutect2, varscan2
- HAVCR2 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV100324756; called by muse, mutect2
- HDAC3 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV100539611, COSV59496882; called by muse, mutect2, varscan2
- HEATR6 | c.3205C>T p.R1069W | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761820133, COSV99482333; called by muse, mutect2, varscan2
- HECA | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100866210; called by muse, mutect2, varscan2
- HEPHL1 | c.1964A>G p.D655G | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100243952; called by muse, mutect2, varscan2
- HERC2 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs146210640; called by muse, mutect2
- HGD | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1313793486, COSV99380960; called by mutect2, varscan2
- HHIP | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs1351392295, COSV99667243; called by muse, mutect2, varscan2
- HOXC8 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99236831; called by muse, mutect2, varscan2
- HRC | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.24); catalogued as COSV53257739, COSV99417930; called by muse, mutect2, varscan2
- HROB | c.1560G>A p.T520= | Splice Region (SNP) | VAF 12/49 reads (24%) | catalogued as rs745993084, COSV55369722; called by muse, mutect2, varscan2
- HSBP1 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV101419156; called by muse, mutect2
- HTR2C | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99349362; called by muse, mutect2, varscan2
- HTT | c.4030C>T p.R1344C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs200657357; called by muse, mutect2, varscan2
- IDE | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs140884087, COSV99794004; called by muse, mutect2, varscan2
- IDH3B | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100250107; called by muse, mutect2
- IFIT2 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs368019671, COSV51079992; called by muse, mutect2, varscan2
- IFNL2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs746951049, COSV59593967; called by muse, mutect2, varscan2
- IFT172 | c.2950C>T p.Q984* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99562505; called by muse, mutect2, varscan2
- IGF2R | c.3704G>A p.G1235D | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as rs763188815, COSV100807384; called by muse, mutect2, varscan2
- IGHV2-26 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs781923250; called by muse, mutect2, varscan2
- IGLC2 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as rs755014029; called by muse, mutect2, varscan2
- IKZF3 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768846820, COSV53103039; called by muse, mutect2, varscan2
- IL10 | c.444+2T>C p.X148_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100894748; called by muse, mutect2, varscan2
- IL20RA | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.51); catalogued as rs774469920, COSV100359967; called by muse, mutect2, varscan2
- IL5RA | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 25/123 reads (20%) | catalogued as COSV99843011; called by muse, mutect2, varscan2
- ILF3 | c.1319G>A p.G440D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV51558558; called by muse, mutect2
- INPP4A | c.2542C>T p.R848W (on ENST00000074304 / NM_001134224.1; = p.R809W on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs773837709, COSV99303890; called by muse, varscan2
- INPP4B | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.487); catalogued as rs1463908639, COSV99524665; called by muse, mutect2, varscan2
- INSL5 | c.358_359del p.L120Vfs*4 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | catalogued as rs747896827; called by mutect2, pindel
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQSEC2 | c.2825G>A p.R942Q (on ENST00000642864 / NM_001111125.3; = p.R737Q on NM_015075.2) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs782651121, COSV100944910; called by muse, mutect2, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- ITGA6 | c.1567C>T p.R523C (on ENST00000442250; = p.R484C on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs545486754, COSV51232171; called by muse, mutect2, varscan2
- ITGB6 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99324546; called by muse, mutect2, varscan2
- ITPR1 | c.7630C>T p.R2544W (on ENST00000354582; = p.R2489W on NM_002222.7) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100231199; called by muse, mutect2, varscan2
- ITSN2 | c.2368del p.T790Pfs*2 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as COSV100742542; called by mutect2, pindel, varscan2
- JMJD1C | c.5213G>A p.R1738H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749176745, COSV100550217; called by muse, mutect2, varscan2
- KALRN | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); catalogued as COSV99562199; called by muse, mutect2, varscan2
- KANK2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754512529, COSV62009478; called by muse, mutect2, varscan2
- KBTBD7 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV101068124; called by muse, mutect2, varscan2
- KCNT2 | c.870C>A p.N290K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV99653745; called by muse, mutect2, varscan2
- KDM4B | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV50248169, COSV50248585; called by muse, mutect2, varscan2
- KIAA0100 | c.3976G>A p.A1326T | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as COSV101197315; called by muse, mutect2, varscan2
- KIAA0100 | c.151del p.W51Gfs*77 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs1339576763; called by pindel, varscan2
- KIAA0319L | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs755794086, COSV57847424; called by muse, mutect2, varscan2
- KIAA1549 | c.4516G>A p.D1506N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1323849555, COSV54334851; called by muse, mutect2
- KIF17 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs769055081, COSV56122092; called by muse, mutect2
- KIF21B | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs779310643, COSV59754240; called by muse, varscan2
- KIF3B | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65228232; called by muse, mutect2, varscan2
- KLF7 | c.203del p.P68Rfs*10 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs1559141567, COSV100518869; called by mutect2, pindel, varscan2
- KLHDC8A | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as COSV100903825; called by muse, mutect2, varscan2
- KLHL12 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63042651; called by muse, mutect2, varscan2
- KLK8 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99143976; called by muse, mutect2
- KMT2B | c.5741G>A p.R1914H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.747); catalogued as rs373804780; called by mutect2, varscan2
- KRIT1 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100388747; called by muse, mutect2, varscan2
- KRT3 | c.1052G>A p.S351N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV58816720; called by mutect2, varscan2
- KSR1 | c.1580C>T p.P527L (on ENST00000644974 / NM_001367810.1; = p.P412L on NM_014238.2) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs754753981, COSV52033172; called by muse, mutect2, varscan2
- KY | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101414990, COSV71016420; called by muse, mutect2, varscan2
- L1CAM | c.3590G>A p.G1197E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.979); catalogued as COSV100649428, COSV62829076; called by muse, mutect2, varscan2
- LAMA3 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs539451824, COSV58066561; called by muse, mutect2, varscan2
- LAMA3 | c.7268C>A p.P2423H (on ENST00000313654 / NM_198129.4; = p.P814H on NM_000227.6) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99334843; called by muse, mutect2, varscan2
- LARP1 | c.2567C>T p.T856M (on ENST00000518297 / NM_033551.3; = p.T779M on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs763112496, COSV60426319; called by muse, mutect2, varscan2
- LARP4 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as rs1408322438, COSV53326132; called by muse, mutect2, varscan2
- LCA5L | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99903616; called by muse, mutect2
- LCAT | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs774093711, COSV99863064; called by muse, varscan2
- LGALS9 | c.1037del p.G346Afs*5 (on ENST00000395473 / NM_009587.3; = p.G314Afs*5 on NM_002308.4) | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs775745717; called by mutect2, pindel, varscan2
- LGI2 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746165455, COSV66122907; called by muse, mutect2, varscan2
- LGSN | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV101040527; called by muse, mutect2
- LIPH | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV56184370; called by muse, mutect2, varscan2
- LMOD3 | c.444A>T p.E148D | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs185938792, COSV70455916; called by muse, mutect2, varscan2
- LPCAT1 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs140641175; called by muse, mutect2, varscan2
- LRBA | c.5923C>T p.R1975C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551089193, COSV100841553; called by muse, mutect2, varscan2
- LRBA | c.5842G>A p.V1948M | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs763165188, COSV100841554; called by muse, varscan2
- LRP1B | c.4723T>A p.F1575I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1461861485, COSV67281513; called by muse, mutect2
- LSG1 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370971373; called by mutect2, varscan2
- LSS | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs779278365, COSV62703048; called by muse, mutect2
- LYST | c.8756C>T p.A2919V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV101089393; called by muse, mutect2, varscan2
- MAD1L1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99642667; called by muse, mutect2, varscan2
- MAGI1 | c.3583C>T p.R1195C (on ENST00000402939 / NM_001033057.2; = p.R1224C on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760886450, COSV100441031; called by muse, mutect2, varscan2
- MAN2B1 | c.2303C>T p.T768M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs757997563, COSV55473877; called by muse, mutect2, varscan2
- MAN2B1 | c.1118A>G p.K373R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99666971; called by muse, mutect2
- MAP2K4 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV100796258; called by muse, mutect2
- MAPKAP1 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV56370082; called by muse, mutect2, varscan2
- MARCHF4 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410905109, COSV56107808; called by muse, mutect2, varscan2
- MAST1 | c.3109G>A p.V1037M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99262958; called by muse, mutect2, varscan2
- MBTD1 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100899190; called by muse, mutect2, varscan2
- MBTPS2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV101068444; called by muse, mutect2, varscan2
- MCC | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs542385466, COSV100202609; called by muse, mutect2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MECP2 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1557137994, COSV100318141, COSV57652299; called by muse, mutect2, varscan2
- MED1 | c.1709del p.G570Vfs*9 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as COSV56128100; called by mutect2, pindel, varscan2
- MELK | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); catalogued as COSV99974630; called by muse, mutect2
- MEP1A | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs756062559, COSV57918066, COSV57922496; called by muse, mutect2
- MFSD4A | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs556886499, COSV100901559; called by muse, mutect2, varscan2
- MIB1 | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.162); catalogued as COSV99838799; called by muse, mutect2, varscan2
- MINDY1 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); catalogued as rs769593812, COSV56500102; called by muse, mutect2, varscan2
- MKI67 | c.5569del p.I1857Yfs*30 | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | catalogued as rs866533107; called by mutect2, pindel, varscan2
- MLH3 | c.1649A>G p.Q550R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1355091236, COSV99470239; called by muse, mutect2, varscan2
- MORF4L1 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100489125; called by muse, mutect2, varscan2
- MPEG1 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs780878835, COSV57093191; called by muse, mutect2, varscan2
- MPP1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV101053687; called by muse, mutect2
- MROH8 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as rs370293792; called by muse, mutect2, varscan2
- MROH8 | c.977A>G p.Q326R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.976); catalogued as COSV99457285; called by muse, mutect2
- MRPL11 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as rs747575624, COSV100207766; called by muse, mutect2, varscan2
- MRPS18B | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99457724; called by muse, mutect2, varscan2
- MRPS9 | c.762del p.K254Nfs*3 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs1297979087; called by mutect2, pindel, varscan2
- MSLN | c.1230G>A p.Q410= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99558308; called by muse, mutect2, varscan2
- MSTN | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs761528049, COSV53620065; called by muse, mutect2, varscan2
- MTFR1 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200858272, COSV50951197; called by muse, mutect2
- MUC15 | c.35C>T p.T12M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs539302971, COSV55552787, COSV99846239; called by muse, mutect2, varscan2
- MUC16 | c.13328G>T p.S4443I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV101199962; called by muse, mutect2, varscan2
- MUC17 | c.2801C>T p.T934M | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768790311, COSV100071056; called by muse, mutect2, varscan2
- MUC4 | c.16237T>C p.*5413Rext*56 (on ENST00000463781 / NM_018406.7; = p.*1177Rext*56 on NM_004532.6) | Nonstop Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100204718; called by mutect2, varscan2
- MXRA5 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs779077720, COSV99476977; called by muse, mutect2, varscan2
- MYCN | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs762164859, COSV99808275; called by muse, mutect2, varscan2
- MYH11 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375159635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH15 | c.5498A>G p.E1833G | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV56307385; called by muse, mutect2
- MYOM2 | c.2313G>A p.T771= | Splice Region (SNP) | VAF 9/57 reads (16%) | catalogued as rs202157103, COSV100037492; called by muse, mutect2, varscan2
- N4BP2L2 | c.641T>G p.L214R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.38); catalogued as COSV99912556; called by muse, mutect2
- NAV1 | c.5110G>A p.D1704N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs747436034, COSV99818850; called by muse, mutect2, varscan2
- NBAS | c.6371G>A p.S2124N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99869746; called by muse, mutect2, varscan2
- NBAS | c.2821C>T p.R941C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs374303460; called by muse, mutect2, varscan2
- NCOA6 | c.5435C>T p.S1812L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs367588060; called by muse, mutect2, varscan2
- NCOA7 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV99997117; called by muse, mutect2, varscan2
- NCOR1 | c.5381G>A p.R1794Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1286197692, COSV51985515; called by muse, mutect2, varscan2
- NCOR2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs986750179, COSV100657336; called by muse, mutect2, varscan2
- NDST1 | c.2426+1G>A p.X809_splice | Splice Site (SNP) | VAF 10/100 reads (10%) | catalogued as rs780360301, COSV55789093; called by muse, mutect2
- NEB | c.16612G>A p.A5538T | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752957835, COSV51123261; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEBL | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs142138590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NELL2 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs200918496, COSV61569411; called by muse, mutect2, varscan2
- NFATC2 | c.2716G>T p.D906Y | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101044100, COSV101044568; called by muse, mutect2, varscan2
- NFKBIZ | c.2006T>C p.V669A | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV100397056; called by muse, mutect2, varscan2
- NFU1 | c.698C>T p.P233L (on ENST00000410022 / NM_001002755.4; = p.P209L on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777602937, COSV100361192; called by muse, mutect2, varscan2
- NHS | c.4789C>T p.R1597C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66278308, COSV66285644; called by muse, mutect2, varscan2
- NMNAT3 | c.190C>T p.R64* (on ENST00000296202 / NM_001320512.1; = p.R27* on NM_178177.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as rs201923390, COSV56155493, COSV56156281; called by muse, mutect2, varscan2
- NMT2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs200842191, COSV65382113; called by muse, mutect2, varscan2
- NRIP1 | c.1168C>G p.P390A | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100012711; called by muse, mutect2, varscan2
- NRP2 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs200906927, COSV99784503; called by muse, varscan2
- NSD3 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1376200162, COSV57618371; called by muse, mutect2
- NUP205 | c.4934T>C p.V1645A | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53654826; called by muse, mutect2, varscan2
- NWD1 | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs374502216; called by muse, mutect2, varscan2
- NWD1 | c.3400G>A p.A1134T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV100342609; called by muse, mutect2, varscan2
- OAF | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1418172517, COSV100202929; called by muse, mutect2
- OAS3 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV99966280; called by muse, mutect2
- OCRL | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV100843445; called by muse, mutect2, varscan2
- ODF2 | c.179G>A p.R60Q (on ENST00000434106 / NM_153433.2; = p.R55Q on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs777136257, COSV100654634; called by muse, mutect2, varscan2
- OR10C1 | c.586A>G p.N196D (on ENST00000622521; = p.N194D on NM_013941.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV101010833; called by muse, mutect2, varscan2
- OR10G3 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100336098; called by muse, mutect2, varscan2
- OR2M2 | c.862del p.L288Sfs*10 | Frame Shift Del (DEL) | VAF 36/160 reads (23%) | catalogued as COSV62898024; called by mutect2, varscan2
- OR2M4 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100141236, COSV100141408; called by muse, mutect2
- OR3A1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs202247230, COSV100041675; called by muse, mutect2, varscan2
- OR3A2 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs748048838, COSV68695124; called by muse, mutect2, varscan2
- OR5K3 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs766061429, COSV101051645; called by muse, mutect2, varscan2
- OR9Q2 | c.461del p.F154Sfs*32 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs1363437757; called by mutect2, pindel, varscan2
- OS9 | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs752513773, COSV99232405; called by mutect2, varscan2
- OTOGL | c.3563G>A p.C1188Y (on ENST00000547103; = p.C1179Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101509268; called by muse, mutect2, varscan2
- OTUB1 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV99735195; called by muse, mutect2, varscan2
- P3H2 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs757331420, COSV60019793; called by muse, varscan2
- PABPC3 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs202153803, COSV55799496; called by muse, mutect2, varscan2
- PAK1IP1 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458453525, COSV99468490; called by muse, mutect2, varscan2
- PAK3 | c.591A>T p.E197D (on ENST00000262836 / NM_001324328.2; = p.E182D on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs764106735, COSV53273699; called by muse, mutect2, varscan2
- PAPOLA | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53485430; called by muse, mutect2, varscan2
- PAPPA2 | c.1799G>A p.C600Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100866787; called by muse, mutect2, varscan2
- PAPPA2 | c.5055del p.S1686Vfs*4 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | catalogued as rs747970462, COSV62809272; called by mutect2, pindel
- PARP1 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759524114, COSV64690478; called by muse, mutect2
- PASK | c.3329G>A p.R1110Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762076400, COSV99299442; called by muse, varscan2
- PAX3 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs745673188, COSV60586370; called by muse, mutect2, varscan2
- PCCA | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66197204; called by muse, mutect2, varscan2
- PCDHA2 | c.1552T>C p.Y518H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.219); catalogued as rs370463257; called by muse, mutect2
- PCDHB7 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.422); catalogued as rs782137017, COSV50757033; called by muse, mutect2
- PCSK2 | c.1535C>T p.T512M | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs754916065, COSV99359588; called by muse, mutect2, varscan2
- PDGFRA | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99956597; called by muse, mutect2, varscan2
- PDS5B | c.3664G>A p.V1222I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs374693255; called by muse, mutect2
- PDXDC1 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs763935663, COSV99816923; called by muse, varscan2
- PGAP2 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as rs774704416, COSV53466645, COSV99544302; called by muse, mutect2, varscan2
- PGM5 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782281328, COSV101123445; called by muse, mutect2, varscan2
- PI4KB | c.871C>T p.R291* (on ENST00000368873 / NM_001369623.1; = p.R303* on NM_002651.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/175 reads (15%) | catalogued as COSV55021152; called by muse, mutect2, varscan2
- PIK3C2B | c.3758G>A p.R1253H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403556784, COSV100916125; called by muse, mutect2, varscan2
- PIK3CA | c.2873A>G p.Q958R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV55995849; called by muse, mutect2, varscan2
- PIK3R5 | c.480C>T p.T160= | Splice Region (SNP) | VAF 8/30 reads (27%) | catalogued as rs201891414, COSV99353331; called by muse, varscan2
- PKD1 | c.2866G>A p.V956M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs748744124, COSV51920636; called by muse, varscan2
- PKD1L1 | c.7946G>A p.S2649N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99219748; called by muse, mutect2, varscan2
- PKHD1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV100583102; called by muse, mutect2, varscan2
- PLA2G4A | c.1466T>C p.V489A | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs758642971, COSV100820542; called by muse, mutect2, varscan2
- PLB1 | c.1944C>A p.F648L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV100215116; called by muse, mutect2, varscan2
- PLIN3 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765582417, COSV55734020; called by muse, mutect2, varscan2
- PLPPR1 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs200604503, COSV66454207; called by muse, mutect2, varscan2
- PLXNA4 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs774798274, COSV58110834; called by muse, mutect2, varscan2
- PNKP | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55588866; called by muse, mutect2
- PNMA2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.83); catalogued as rs751080139, COSV101580621; called by muse, mutect2, varscan2
- POLR3C | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV61936607; called by muse, mutect2, varscan2
- POM121C | c.1472G>A p.R491Q (on ENST00000607367; = p.R249Q on NM_001099415.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs781963167, COSV99992721; called by muse, mutect2, varscan2
- POP1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs781072902, COSV62892312, COSV62893554; called by muse, mutect2, varscan2
- PPEF2 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); catalogued as rs143649959; called by muse, mutect2, varscan2
- PPFIA4 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs780862151, COSV99829953; called by muse, mutect2, varscan2
- PPP1R12A | c.2527C>T p.R843* | Nonsense Mutation (SNP) | VAF 42/189 reads (22%) | catalogued as COSV99700389; called by muse, mutect2, varscan2
- PPP1R13L | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV62909198; called by muse, mutect2
- PPP1R16B | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs140211111; called by muse, mutect2, varscan2
- PPP1R26 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs868766086, COSV100778044; called by muse, mutect2
- PPP1R8 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.262); catalogued as rs774283162, COSV99360985; called by muse, mutect2, varscan2
- PPP3R2 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV62457005; called by muse, mutect2, varscan2
- PPP4R1 | c.1897C>T p.R633C (on ENST00000400556 / NM_001042388.3; = p.R616C on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs757193618, COSV99553497; called by muse, mutect2, varscan2
- PPP6R3 | c.2451-1G>A p.X817_splice (on ENST00000393800 / NM_001352375.2; = p.X737_splice on NM_018312.5) | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99676450; called by muse, mutect2, varscan2
- PRKAA1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); catalogued as rs866107019, COSV57186113; called by muse, mutect2, varscan2
- PRKCA | c.545del p.N182Ifs*2 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | catalogued as rs773101122; called by mutect2, pindel, varscan2
- PRKCD | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as rs781914241, COSV57850156; ClinVar: uncertain significance; called by muse, mutect2
- PRKDC | c.11504C>T p.P3835L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV100040588; called by muse, mutect2, varscan2
- PRTG | c.2143C>T p.R715C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1279671217, COSV101221382; called by muse, mutect2, varscan2
- PSMC5 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV99856420; called by muse, mutect2, varscan2
- PSPC1 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as rs199997572; called by muse, mutect2, varscan2
- PTDSS2 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.765); catalogued as rs763361010, COSV100339174; called by muse, mutect2, varscan2
- PTHLH | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1350620386, COSV52368103; called by muse, mutect2, varscan2
- PTPN3 | c.2356C>T p.R786* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs770792229, COSV52705632, COSV52709603; called by muse, mutect2
- PTPN7 | c.147G>A p.M49I (on ENST00000495688; = p.M88I on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100459877; called by muse, mutect2, varscan2
- PUS7 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs764174199, COSV100708550; called by muse, mutect2, varscan2
- PVR | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99495796; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as rs755727862; called by mutect2, varscan2
- RAD50 | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs367925756, COSV54755388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAD51C | c.1040G>A p.R347K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100506977; called by muse, varscan2
- RASAL2 | c.390_392del p.R131del | In Frame Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs753921536; called by pindel, varscan2
- RASL11A | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.065); catalogued as rs747958383, COSV99611038; called by mutect2, varscan2
- RASSF2 | c.770T>A p.V257E | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101040764; called by muse, mutect2, varscan2
- RBPJ | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.204); catalogued as rs753437611, COSV60748609; called by muse, mutect2, varscan2
- RC3H2 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs777562155, COSV59010468; called by muse, mutect2, varscan2
- RFC4 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV99961218; called by muse, mutect2
- RFTN1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs1217495195, COSV100489321, COSV61921945; called by muse, mutect2, varscan2
- RFX4 | c.1676C>T p.T559M (on ENST00000392842 / NM_213594.3; = p.T465M on NM_032491.6) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs778021053, COSV57582524; called by muse, mutect2, varscan2
- RGL3 | c.1647C>T p.S549= | Splice Region (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100992958; called by muse, mutect2, varscan2
- RGS12 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs774203817, COSV100122896; called by muse, mutect2, varscan2
- RHNO1 | c.301T>C p.S101P | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV100817045; called by muse, mutect2, varscan2
- RHOT2 | c.1556G>A p.C519Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54809578; called by mutect2, varscan2
- RHOU | c.306T>A p.C102* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100797165; called by muse, mutect2, varscan2
- RIC8B | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1425424627, COSV62694732; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RNASE4 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100489354; called by muse, mutect2, varscan2
- RNF207 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as rs200801968, COSV100933739; called by muse, mutect2
- RNF213 | c.8938G>A p.A2980T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.139); catalogued as rs1361993119, COSV60393657, COSV60398609; called by muse, mutect2, varscan2
- RNPEPL1 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99549511; called by muse, mutect2
- ROBO1 | c.4045C>T p.R1349C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); catalogued as rs1262951258, COSV71394454; called by muse, mutect2, varscan2
- ROBO1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745910529, COSV101458721; called by muse, mutect2, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- ROS1 | c.2165C>T p.T722M | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs372637439, COSV63859270; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV100271655; called by muse, mutect2, varscan2
- RPRD1A | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100442012; called by muse, mutect2, varscan2
- RPS3A | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as rs533195948, COSV99923671; called by muse, mutect2, varscan2
- RSAD1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148371199, COSV51954634; called by muse, mutect2, varscan2
- RSPH10B | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs750994227, COSV61756311; called by muse, mutect2, varscan2
- RTKN | c.896G>A p.R299H (on ENST00000272430 / NM_001015055.2; = p.R286H on NM_033046.2) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376959473, COSV99269632; called by mutect2, varscan2
- RTL5 | c.1523A>G p.N508S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV101030102; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as rs756606313; called by mutect2, varscan2
- RUFY4 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs377117730, COSV60247772; called by muse, mutect2, varscan2
- RUNX1 | c.415C>T p.R139* (on ENST00000344691 / NM_001001890.3; = p.R166* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 34/84 reads (40%) | catalogued as rs759068561, CM1110604, COSV55866510, COSV55867075; called by muse, mutect2, varscan2
- SBK1 | c.227-2A>G p.X76_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100543519; called by muse, mutect2, varscan2
- SCN11A | c.4564G>A p.V1522M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs965494346, COSV100181566; called by muse, mutect2, varscan2
- SCN1A | c.3817G>A p.A1273T (on ENST00000303395 / NM_001202435.3; = p.A1262T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100320447; called by muse, mutect2, varscan2
- SCN9A | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs775461240, COSV57604465; called by muse, mutect2, varscan2
- SDK1 | c.2479G>A p.V827M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs754010999, COSV101269363; called by muse, mutect2, varscan2
- SEC16B | c.2756G>A p.R919Q | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs547151020, COSV100381584; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC63 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV100938384; called by muse, mutect2, varscan2
- SELENON | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100823504; called by muse, mutect2, varscan2
- SELL | c.325G>T p.G109* (on ENST00000650983; = p.G96* on NM_000655.5) | Nonsense Mutation (SNP) | VAF 11/106 reads (10%) | catalogued as COSV99357578; called by muse, mutect2, varscan2
- SEMA3G | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs779557827, COSV99202342; called by muse, varscan2
- SEMA6C | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1025677715, COSV100501314; called by muse, mutect2, varscan2
- SENP7 | c.2573+1G>A p.X858_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as rs1477839754, COSV58612718; called by muse, mutect2, varscan2
- SERPINA6 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV100448298; called by muse, mutect2, varscan2
- SGF29 | c.524G>A p.W175* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100187147; called by muse, mutect2, varscan2
- SH2D1B | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100854814; called by muse, mutect2, varscan2
- SH3BP4 | c.1208del p.N403Mfs*14 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV100749003; called by mutect2, pindel, varscan2
- SHLD2 | c.2041C>A p.H681N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.107); catalogued as COSV100079181; called by muse, mutect2, varscan2
- SIL1 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.53); catalogued as rs201418882; called by mutect2, varscan2
- SIM1 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs756633599, CM136552, COSV99492361; called by muse, mutect2, varscan2
- SIPA1L1 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.99); catalogued as rs746170225, COSV100665551; called by muse, varscan2
- SIPA1L1 | c.177T>G p.S59R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100665552; called by muse, varscan2
- SLC16A4 | c.758_759del p.T253Sfs*7 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs1355370674; called by mutect2, pindel, varscan2
- SLC16A7 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750421578, COSV99676511; called by muse, mutect2, varscan2
- SLC24A3 | c.1218G>T p.E406D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100041184; called by muse, mutect2, varscan2
- SLC25A35 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150820162; called by muse, varscan2
- SLC29A4 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs746420671, COSV51876883; called by muse, mutect2, varscan2
- SLC2A14 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.16); catalogued as COSV100533813; called by muse, mutect2, varscan2
- SLC2A4 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs766922260, COSV50300479; called by muse, mutect2, varscan2
- SLC30A5 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV101080712; called by mutect2, varscan2
- SLC37A3 | c.1282G>T p.G428* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100405459; called by muse, mutect2
- SLC44A1 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV101029346; called by muse, mutect2, varscan2
- SLC4A5 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs765679180, COSV61024422; called by muse, mutect2, varscan2
- SLC66A1 | c.164+1G>A p.X55_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100913233; called by muse, mutect2, varscan2
- SLC6A1 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.971); catalogued as COSV99822750; called by mutect2, varscan2
- SLC7A9 | c.83A>C p.K28T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV99195289; called by mutect2, varscan2
- SLU7 | c.1701G>T p.E567D | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV99775622; called by muse, mutect2, varscan2
- SMARCAL1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as CM101359, COSV61921972; called by muse, mutect2, varscan2
- SMC1A | c.3361C>T p.R1121C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447393; called by muse, mutect2, varscan2
- SMC2 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs776518199, COSV53955324; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as rs760667210; called by mutect2, varscan2
- SMG1 | c.4522G>A p.A1508T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as COSV101246019; called by muse, mutect2, varscan2
- SMG6 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53976679; called by muse, mutect2, varscan2
- SMPD2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368023431; called by muse, mutect2, varscan2
- SNED1 | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374273335; called by muse, mutect2
- SNED1 | c.4119C>T p.H1373= | Splice Region (SNP) | VAF 7/68 reads (10%) | catalogued as rs766375001, COSV99612594; called by muse, mutect2, varscan2
- SNRK | c.2188G>A p.V730M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as rs572465919, COSV56066869; called by mutect2, varscan2
- SOAT2 | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV100037482; called by muse, mutect2, varscan2
- SP1 | c.233G>A p.S78N (on ENST00000327443 / NM_138473.3; = p.S71N on NM_003109.1) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100540639; called by muse, mutect2, varscan2
- SP110 | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs773059144, COSV99283413; called by muse, mutect2, varscan2
- SPAG17 | c.4514G>A p.C1505Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100309130, COSV60461086; called by muse, mutect2, varscan2
- SPATA20 | c.1039C>T p.Q347* (on ENST00000356488 / NM_001258372.1; = p.Q363* on NM_022827.4) | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99136007; called by muse, mutect2, varscan2
- SPATA22 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779059023, COSV52153610; called by mutect2, varscan2
- SPATA31D1 | c.4532G>A p.C1511Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV100782787; called by muse, mutect2, varscan2
- SPATA4 | c.425A>T p.E142V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV99708965; called by muse, varscan2
- SPEG | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs758282857, COSV56679940; called by muse, mutect2, varscan2
- SPTY2D1 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs746473954, COSV100311675; called by mutect2, varscan2
- SRCAP | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767188034, COSV52680171; called by muse, mutect2, varscan2
- SRGAP1 | c.2129C>G p.A710G | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100754699; called by muse, mutect2
- SRP72 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1449936670, COSV61378044; called by muse, mutect2, varscan2
- SRRM2 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs765477905, COSV100070806, COSV100071577; called by muse, mutect2
- SRSF8 | c.813del p.K272Sfs*21 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs781928250; called by mutect2, pindel, varscan2
- SSB | c.430A>G p.R144G | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV99641699; called by muse, mutect2, varscan2
- SSBP2 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100283522; called by mutect2, varscan2
- SSR4 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs887246891, COSV99381338; called by muse, mutect2, varscan2
- STOM | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs745770275, COSV54417246; called by muse, mutect2, varscan2
- SUCLA2 | c.914G>A p.R305H (on ENST00000643023; = p.R284H on NM_003850.3) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs771276854, COSV66221898; called by muse, mutect2, varscan2
- SUGCT | c.1255G>A p.D419N (on ENST00000335693 / NM_001193313.2; = p.D445N on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs769042792, COSV59337882; called by muse, varscan2
- SULT1B1 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as rs369976377; called by mutect2, varscan2
- SUPT4H1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1235704992, COSV99842770; called by muse, mutect2, varscan2
- SUPT6H | c.4666C>T p.P1556S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV99972696; called by muse, mutect2, varscan2
- SVEP1 | c.6238G>T p.A2080S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52837131, COSV99929032; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs753462162; called by mutect2, varscan2
- SYCP2 | c.2869C>G p.P957A | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.077); catalogued as COSV100698257; called by muse, mutect2, varscan2
- SYNE1 | c.22304G>A p.R7435H (on ENST00000367255 / NM_182961.4; = p.R7364H on NM_033071.3) | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs748260996, COSV54967384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.17890C>T p.R5964C (on ENST00000367255 / NM_182961.4; = p.R5893C on NM_033071.3) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs748231030, COSV54952601; called by muse, mutect2, varscan2
- SYNE1 | c.11424C>A p.H3808Q (on ENST00000367255 / NM_182961.4; = p.H3793Q on NM_033071.3) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV99564443; called by muse, mutect2, varscan2
- TARS3 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as rs751025366, COSV60109835; called by muse, mutect2, varscan2
- TAS2R41 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs761627851, COSV101281465; called by muse, mutect2, varscan2
- TBC1D12 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs377630453; called by muse, mutect2, varscan2
- TBCD | c.485T>G p.L162R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100833246; called by muse, mutect2, varscan2
- TBCE | c.889G>A p.A297T (on ENST00000366601; = p.A360T on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as rs1456103722, COSV64006271; called by muse, mutect2, varscan2
- TCEAL8 | c.182T>C p.F61S | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs1286763243, COSV100749823; called by muse, mutect2
- TCF7L2 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.04); catalogued as rs200865074; called by muse, mutect2, varscan2
- TENM1 | c.5630C>T p.A1877V | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV100950051; called by muse, mutect2, varscan2
- TEP1 | c.6419G>A p.R2140Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs560009498, COSV99402415; called by muse, varscan2
- TET1 | c.365T>C p.V122A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1356016602, COSV101018249; called by muse, mutect2, varscan2
- TET2 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs768227565, COSV54417397, COSV54426565; called by muse, varscan2
- THBS1 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.791); catalogued as rs746481802, COSV99527926; called by mutect2, varscan2
- THRB | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as COSV99769473; called by muse, mutect2, varscan2
- THRB | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs750046403, COSV100726142; called by muse, varscan2
- THSD7B | c.2765C>A p.P922H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99750954; called by muse, mutect2, varscan2
- TLR5 | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs200696063, COSV60558441; called by muse, mutect2, varscan2
- TMBIM1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs144751225; called by muse, mutect2
- TMEM128 | c.172G>A p.A58T (on ENST00000382753 / NM_001297552.2; = p.A34T on NM_032927.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV99632086; called by mutect2, varscan2
- TMEM150C | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs765257134, COSV101497308; called by muse, mutect2, varscan2
- TMEM183A | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100923848; called by muse, mutect2
- TMEM30A | c.469T>C p.C157R | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100034901; called by muse, mutect2, varscan2
- TMEM39B | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100298021; called by muse, mutect2, varscan2
- TMEM40 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.229); catalogued as rs781731021, COSV99277065; called by muse, mutect2, varscan2
- TMEM40 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as rs146365508; called by muse, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM68 | c.352del p.I118Yfs*9 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as COSV58173042; called by mutect2, pindel, varscan2
- TMEM86A | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99773751; called by muse, mutect2, varscan2
- TMEM87B | c.773del p.L258Wfs*27 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | catalogued as rs750138307; called by mutect2, pindel, varscan2
- TMOD4 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs969428801, COSV99766023; called by muse, mutect2, varscan2
- TMTC4 | c.1834G>A p.V612M (on ENST00000376234 / NM_001350577.2; = p.V631M on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs112049465, COSV60893693; called by muse, mutect2, varscan2
- TNFAIP1 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99134648; called by muse, mutect2, varscan2
- TNFRSF1B | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201574750, COSV66165022; called by mutect2, varscan2
- TNPO3 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768657564, COSV99602956; called by muse, mutect2, varscan2
- TOPORS | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV62117375; called by muse, mutect2, varscan2
- TPBG | c.793C>A p.L265M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869782; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1486A>G p.K496E | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100389743; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037dup p.G680Wfs*3 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs770561785; called by mutect2, varscan2
- TRAPPC9 | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101227456, COSV101228295; called by muse, mutect2, varscan2
- TRAV24 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs1382079401; called by muse, mutect2, varscan2
- TRIM25 | c.1264+1G>A p.X422_splice | Splice Site (SNP) | VAF 21/79 reads (27%) | catalogued as rs752704891, COSV100380995; called by muse, mutect2, varscan2
- TRIM25 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs769575690, COSV100380996; called by muse, mutect2, varscan2
- TRIM42 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.118); catalogued as rs369004181; called by muse, varscan2
- TRIML1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs752025162, COSV60194996; called by muse, mutect2, varscan2
- TRIP12 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs749529404, COSV99390276; called by muse, mutect2, varscan2
- TRPC1 | c.2204T>C p.M735T (on ENST00000476941 / NM_001251845.2; = p.M701T on NM_003304.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as COSV99858797; called by muse, mutect2, varscan2
- TRPM8 | c.917A>G p.Q306R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs1165420556, COSV100224052; called by muse, mutect2, varscan2
- TSPYL4 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as rs1484148404, COSV60305656; called by muse, mutect2, varscan2
- TTC5 | c.740T>C p.F247S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99351804; called by muse, mutect2, varscan2
- TTC8 | c.1562T>G p.I521S (on ENST00000338104 / NM_001288781.1; = p.I505S on NM_144596.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.239); catalogued as COSV100581334; called by muse, mutect2, varscan2
- TTN | c.96257A>G p.E32086G (on ENST00000591111; = p.E24662G on NM_003319.4) | Missense Mutation (SNP) | VAF 22/93 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV100612866; called by muse, mutect2, varscan2
- TTN | c.80516G>A p.G26839D (on ENST00000591111; = p.G19415D on NM_003319.4) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | PolyPhen probably damaging (1); catalogued as COSV100612868; called by muse, mutect2, varscan2
- TTN | c.55892C>T p.P18631L (on ENST00000591111; = p.P11207L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | PolyPhen probably damaging (0.999); catalogued as rs760277470, COSV100612870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.48874T>C p.Y16292H (on ENST00000591111; = p.Y8868H on NM_003319.4) | Missense Mutation (SNP) | VAF 7/87 reads (8%) | PolyPhen probably damaging (0.974); catalogued as COSV100612874; called by muse, mutect2
- TTN | c.37924C>T p.R12642C (on ENST00000591111; = p.R5218C on NM_003319.4) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | PolyPhen possibly damaging (0.606); catalogued as rs199684560, COSV60026680; called by muse, mutect2, varscan2
- TUBA8 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.069); catalogued as rs371735188; called by muse, mutect2, varscan2
- TUBGCP3 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99996877; called by muse, mutect2
- TULP2 | c.1184A>G p.N395S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99667863; called by muse, mutect2, varscan2
- TXNL4B | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99194315; called by muse, mutect2, varscan2
- UBAP2 | c.1258C>A p.L420I | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV100671385; called by muse, mutect2, varscan2
- UBOX5 | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV99417915; called by muse, mutect2, varscan2
- UBR1 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99317239; called by muse, mutect2
- UBTD2 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs752260370, COSV67144031; called by muse, mutect2, varscan2
- UGGT2 | c.2444A>T p.K815M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100948683; called by muse, mutect2
- UNC13B | c.2374C>T p.R792C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751894353, COSV65932638; called by muse, mutect2, varscan2
- UNC13C | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs751934604, COSV99517335; called by muse, mutect2, varscan2
- USO1 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as COSV99362817; called by muse, mutect2, varscan2
- USP25 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99583792; called by muse, mutect2, varscan2
- USP32 | c.4081del p.S1361Afs*85 | Frame Shift Del (DEL) | VAF 21/116 reads (18%) | catalogued as COSV56267843; called by mutect2, pindel, varscan2
- USP35 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100416513, COSV60866394; called by muse, mutect2, varscan2
- USP38 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100189256; called by muse, mutect2
- USP40 | c.3441del p.K1147Nfs*12 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs572063854; called by mutect2, varscan2
- USP53 | c.583A>G p.R195G | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV99917740; called by muse, mutect2
- VARS2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776585917, COSV52560100; called by muse, mutect2
- VAT1 | c.713T>A p.I238N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99887837; called by muse, mutect2, varscan2
- VSIG8 | c.115A>G p.N39D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV100928796; called by muse, mutect2, varscan2
- WDFY3 | c.8485C>T p.R2829C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs749089254, COSV99883019; called by muse, mutect2, varscan2
- WDR44 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs753819771, COSV54164822; called by muse, mutect2, varscan2
- WNK4 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs763311211, COSV53821803, COSV99519422; called by muse, mutect2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by mutect2, pindel, varscan2
- WWP2 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs139105338; called by muse, varscan2
- XDH | c.1038G>A p.A346= | Splice Region (SNP) | VAF 8/41 reads (20%) | catalogued as rs557992688, COSV65147845; called by muse, mutect2, varscan2
- XPNPEP2 | c.237C>T p.N79= | Splice Region (SNP) | VAF 12/106 reads (11%) | catalogued as rs781772206, COSV64367866; called by muse, mutect2, varscan2
- XRCC5 | c.589A>C p.I197L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101079567; called by muse, mutect2, varscan2
- YEATS2 | c.1786G>A p.G596S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as rs772726734, COSV100527814; called by muse, mutect2, varscan2
- YES1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100099578; called by muse, mutect2, varscan2
- ZAN | c.7510G>A p.A2504T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs375489174, COSV61816823; called by muse, varscan2
- ZBED9 | c.2972C>T p.A991V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as rs141069135; called by muse, mutect2, varscan2
- ZBTB44 | c.866T>A p.V289D | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV100777275, COSV63538628; called by muse, mutect2, varscan2
- ZBTB49 | c.461del p.P154Lfs*99 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as rs759403850; called by mutect2, pindel, varscan2
- ZC2HC1C | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs768393986, COSV99472873; called by muse, mutect2, varscan2
- ZC3H13 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.116); catalogued as rs1270958848, COSV54454838; called by muse, mutect2, varscan2
- ZC3H3 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99367839; called by muse, mutect2, varscan2
- ZCCHC12 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs756306063, COSV59571510; called by muse, mutect2, varscan2
- ZCWPW2 | c.651del p.R219Gfs*25 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV67498405, COSV67501170; called by mutect2, pindel, varscan2
- ZDHHC19 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs531901034, COSV99579594; called by muse, varscan2
- ZFHX4 | c.7023T>A p.D2341E | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.99); PolyPhen benign (0.028); catalogued as COSV99262773; called by muse, mutect2, varscan2
- ZFHX4 | c.9287C>T p.T3096I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV99262781; called by muse, mutect2, varscan2
- ZFP91 | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs770502239, COSV60159924; called by muse, mutect2, varscan2
- ZFYVE19 | c.283G>A p.G95S (on ENST00000355341 / NM_001077268.2; = p.G85S on NM_032850.5) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); catalogued as rs778312898, COSV99591682; called by muse, mutect2, varscan2
- ZKSCAN2 | c.805G>T p.G269* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as rs868233963, COSV100048186; called by muse, mutect2
- ZMAT5 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100722632; called by muse, mutect2, varscan2
- ZNF100 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773307079, COSV99974022; called by muse, mutect2, varscan2
- ZNF117 | c.1332del p.Y445Tfs*21 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as COSV99276030; called by mutect2, pindel, varscan2
- ZNF132 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs202158029, COSV99571152; called by muse, mutect2, varscan2
- ZNF160 | c.2117G>C p.R706P | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs201073674, COSV100762333, COSV62001625; called by muse, mutect2, varscan2
- ZNF165 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.151); catalogued as rs753844384, COSV66102642; called by muse, mutect2, varscan2
- ZNF175 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs767219802, COSV99219503; called by muse, mutect2, varscan2
- ZNF184 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV53004421; called by muse, mutect2, varscan2
- ZNF197 | c.2552G>A p.C851Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100482093; called by mutect2, varscan2
- ZNF2 | c.344C>T p.A115V (on ENST00000611147 / NM_001291605.2; = p.A102V on NM_021088.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as rs557578807, COSV99728470; called by muse, mutect2, varscan2
- ZNF202 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752414542, COSV100279041; called by muse, mutect2, varscan2
- ZNF222 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99496359; called by muse, mutect2, varscan2
- ZNF227 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as rs372438602; called by muse, mutect2, varscan2
- ZNF239 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100021805; called by muse, mutect2, varscan2
- ZNF257 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV101448101; called by muse, mutect2, varscan2
- ZNF304 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs370744975; called by muse, mutect2, varscan2
- ZNF318 | c.4045C>T p.R1349* | Nonsense Mutation (SNP) | VAF 38/121 reads (31%) | catalogued as rs746170618, COSV100546181; called by muse, mutect2, varscan2
- ZNF318 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 31/119 reads (26%) | catalogued as rs776938166, COSV100546184; called by muse, mutect2, varscan2
- ZNF320 | c.460A>T p.I154F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.305); catalogued as COSV101206863; called by muse, mutect2, varscan2
- ZNF330 | c.911T>C p.L304S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV99522489; called by muse, mutect2, varscan2
- ZNF335 | c.1807T>C p.Y603H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs16990961; called by muse, mutect2
- ZNF35 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs755227333, COSV99940047; called by muse, mutect2, varscan2
- ZNF382 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs764611801, COSV99497781; called by muse, mutect2, varscan2
- ZNF382 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs751264916, COSV99497808; called by muse, mutect2, varscan2
- ZNF383 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100776754; called by muse, mutect2, varscan2
- ZNF394 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100529886, COSV100529927; called by muse, mutect2, varscan2
- ZNF425 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs374027953; called by muse, mutect2, varscan2
407 further variants in this file (129 protein-altering or splice-affecting, 245 silent, 33 other) are not listed here.
